Somatic mutation profile of tumor specimen C3N-03211-01 (aliquot CPT0209640008) from CPTAC case C3N-03211, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 43.9 years (16,048 days).
Specimen C3N-03211-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5195ce9-dcc5-439f-a864-56f924b0373f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03211-31 (Blood Derived Normal), aliquot CPT0209690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fea0baea-e73d-4e11-9e8e-ee4cf96dc5e4

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 48/610 reads (8%) | catalogued as rs730881970, CM041079, COSV58822821; ClinVar: pathogenic; called by muse, mutect2
- KMT2D | c.5125C>T p.R1709C | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1372083024, CD122089; called by muse, mutect2
- ATF7 | c.893C>T p.T298I (on ENST00000548446 / NM_001366555.2; = p.T287I on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/616 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- UNC13D | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- HOXA3 | c.999G>A p.G333= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- LRFN1 | c.825C>T p.C275= | Silent (SNP) | VAF 46/828 reads (6%) | catalogued as rs766080025; called by muse, mutect2
- LRRTM4 | c.987C>T p.F329= | Silent (SNP) | VAF 14/197 reads (7%) | called by muse, mutect2
- MUC16 | c.6189T>G p.T2063= | Silent (SNP) | VAF 19/333 reads (6%) | catalogued as COSV67464182; called by muse, mutect2
- PKHD1 | c.9576C>T p.S3192= | Silent (SNP) | VAF 50/1067 reads (5%) | catalogued as rs201670044, COSV61887442; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- PRDM5 | c.744-37C>T | Intron (SNP) | VAF 30/707 reads (4%) | called by muse, mutect2
